Somatic mutation profile of tumor specimen TCGA-CJ-6033-01A (aliquot TCGA-CJ-6033-01A-11D-1669-08) from TCGA case TCGA-CJ-6033, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 54.5 years (19,919 days).
Specimen TCGA-CJ-6033-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4af0cc40-5af5-425b-a358-863136027a14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-6033-11A (Solid Tissue Normal), aliquot TCGA-CJ-6033-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/025c3ffe-d6be-4da8-98a1-d4e1cf1a1266

The open-access MAF lists 83 somatic variants for this specimen: 61 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 20, Splice Site 3, Intron 1, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/90 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACE | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs372626836; called by muse, mutect2, varscan2
- ACSS3 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as rs776097345, COSV54091174; called by muse, mutect2, varscan2
- AGT | c.1247A>G p.N416S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV64184552; called by muse, mutect2, varscan2
- APOL5 | c.1121C>G p.P374R | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.724); catalogued as COSV50766902; called by muse, mutect2, varscan2
- ARSG | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.079); catalogued as COSV71593166; called by muse, mutect2, varscan2
- CEACAM3 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV55761538; called by muse, mutect2, varscan2
- CENPF | c.5653A>T p.N1885Y | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV65274961; called by muse, mutect2, varscan2
- CHSY3 | c.1884C>G p.I628M | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV59277467; called by muse, mutect2, varscan2
- COL24A1 | c.3735+2T>C p.X1245_splice | Splice Site (SNP) | VAF 31/264 reads (12%) | catalogued as COSV65306343; called by muse, mutect2, varscan2
- DCC | c.3688C>A p.P1230T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV71431914; called by muse, mutect2, varscan2
- DLD | c.737G>C p.G246A | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV52737957; called by muse, mutect2, varscan2
- DNAJC25 | c.511T>C p.Y171H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57956730; called by muse, mutect2, varscan2
- DOCK11 | c.869A>T p.Q290L | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV52238979; called by muse, mutect2
- DOCK11 | c.6188G>A p.R2063Q | Missense Mutation (SNP) | VAF 62/221 reads (28%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.028); catalogued as rs772498571, COSV52238991; called by muse, mutect2, varscan2
- DUSP21 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.862); catalogued as rs768144151, COSV59134155, COSV59134895; called by muse, mutect2, varscan2
- FNDC3B | c.2068T>G p.L690V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs557648244, COSV61042278; called by muse, mutect2, varscan2
- FRMPD2 | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV59717956; called by muse, mutect2, varscan2
- GALNT13 | c.1502G>C p.G501A | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV67221076, COSV67234015; called by muse, mutect2, varscan2
- GALT | c.1022T>C p.M341T | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1248681332, COSV58840612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRM1 | c.2549T>G p.F850C | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51146253; called by muse, mutect2
- HIF1A | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60189250; called by muse, mutect2, varscan2
- IFIT2 | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs775027680, COSV51078970, COSV99260146; called by muse, mutect2, varscan2
- IFNA14 | c.235G>T p.V79F | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV66516132; called by muse, mutect2, varscan2
- KDM2A | c.2405C>T p.T802M | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs780770391, COSV58189611; called by muse, mutect2, varscan2
- KLRD1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.303); catalogued as rs1163229409, COSV60273669; called by muse, mutect2
- LILRB4 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs1276750709, COSV54405123; called by muse, mutect2
- MACF1 | c.311A>G p.E104G | Missense Mutation (SNP) | VAF 22/196 reads (11%) | catalogued as COSV57103007; called by muse, mutect2, varscan2
- MED18 | c.379C>G p.H127D | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as COSV65790564; called by muse, mutect2, varscan2
- MMGT1 | c.325T>A p.S109T | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV60003340; called by muse, mutect2, varscan2
- MSH4 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.098); catalogued as COSV54202830, COSV54206321; called by muse, mutect2, varscan2
- MXRA8 | c.1237A>T p.I413F | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV58510582; called by muse, mutect2
- MYLK | c.4070A>T p.Y1357F | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV60610180; called by muse, mutect2
- MYLK2 | c.1280T>G p.F427C | Missense Mutation (SNP) | VAF 70/267 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65659048; called by muse, mutect2, varscan2
- NDST1 | c.2609T>C p.L870P | Missense Mutation (SNP) | VAF 76/551 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV55787247; called by muse, mutect2, varscan2
- NEU1 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754068739, CM004862, COSV57667223; called by muse, mutect2, varscan2
- NEXMIF | c.2871A>T p.Q957H | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV50030945; called by muse, mutect2, varscan2
- NGB | c.322A>T p.T108S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV53611398; called by muse, mutect2, varscan2
- NNT | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs867401878, COSV52925039; called by muse, mutect2, varscan2
- OSGIN2 | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52408554; called by muse, mutect2, varscan2
- PBRM1 | c.3534-1G>C p.X1178_splice (on ENST00000296302 / NM_001366071.2; = p.X1153_splice on NM_018313.5) | Splice Site (SNP) | VAF 15/38 reads (39%) | catalogued as COSV56273240, COSV56276054, COSV56293635; called by muse, mutect2, varscan2
- PDZD2 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.323); catalogued as COSV56858312; called by muse, mutect2, varscan2
- PLOD2 | c.1294T>A p.L432M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV51464806; called by muse, mutect2, varscan2
- POP7 | c.9A>C p.E3D | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV57450135; called by muse, mutect2, varscan2
- PTPDC1 | c.661C>T p.R221W (on ENST00000375360 / NM_177995.3; = p.R273W on NM_152422.4) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547059455, COSV56622610; called by muse, mutect2, varscan2
- RBM46 | c.538A>G p.K180E | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV55978833; called by muse, mutect2, varscan2
- RLBP1 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs750355323, COSV51528091; called by muse, mutect2, varscan2
- SLC12A6 | c.803T>C p.V268A (on ENST00000354181 / NM_001365088.1; = p.V217A on NM_005135.2) | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51625697, COSV51626012; called by muse, mutect2, varscan2
- SMCR8 | c.1684A>C p.S562R | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV58177373; called by muse, mutect2, varscan2
- SOX4 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55193191; called by muse, mutect2, varscan2
- SPIN3 | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100888471, COSV66529185; called by muse, mutect2, varscan2
- SS18 | c.730A>G p.M244V | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.012); catalogued as COSV52260975; called by muse, mutect2, varscan2
- STRN | c.1574G>A p.S525N | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.678); catalogued as COSV55747887; called by muse, mutect2, varscan2
- TRANK1 | c.1915G>A p.G639S | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV57150140; called by muse, mutect2, varscan2
- USP40 | c.2243T>G p.I748S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as COSV52480846; called by muse, mutect2, varscan2
- XIRP2 | c.3126G>C p.E1042D (on ENST00000628543; = p.E1217D on NM_152381.6) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as COSV54700086; called by mutect2, varscan2
- YTHDF2 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV65722833; called by muse, mutect2, varscan2
- ZNF883 | c.856A>C p.I286L | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV71309066; called by muse, mutect2, varscan2
- DNAH3 | c.4347+1del p.X1449_splice | Splice Site (DEL) | VAF 28/157 reads (18%) | called by mutect2, pindel, varscan2
- SLC14A2 | c.1609_1610delinsA p.S537Tfs*28 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by pindel, varscan2*
- UQCRC2 | c.984_998del p.S329_S333del | In Frame Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel
- ACP6 | c.856T>C p.L286= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV65076882, COSV65077306; called by muse, mutect2, varscan2
- BMPR2 | c.468A>G p.A156= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as COSV65809394; called by muse, mutect2
- DSCAML1 | c.568C>A p.R190= (on ENST00000321322; = p.R130= on NM_020693.4) | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV58390642; called by muse, mutect2, varscan2
- DUOXA2 | c.282C>T p.R94= | Silent (SNP) | VAF 22/219 reads (10%) | catalogued as COSV50993560; called by muse, mutect2, varscan2
- EPPK1 | c.5799G>T p.A1933= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV73261256; called by muse, mutect2, varscan2
- FAT1 | c.8829G>T p.T2943= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV71673899, COSV71675392; called by muse, mutect2, varscan2
- GPR78 | c.873G>A p.P291= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs148589120; called by muse, mutect2, varscan2
- ISCU | c.357T>C p.T119= (on ENST00000311893 / NM_213595.4; = p.T94= on NM_014301.4) | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV57810016; called by muse, mutect2, varscan2
- ISL1 | c.732G>A p.K244= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV57933577; called by muse, mutect2, varscan2
- LLGL1 | c.255C>T p.T85= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs551770657, COSV57497934; called by muse, mutect2, varscan2
- MRE11 | c.1974C>T p.T658= (on ENST00000323929 / NM_005591.4; = p.T630= on NM_005590.4) | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs772019392, COSV60576862; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NPPB | c.123C>T p.S41= | Silent (SNP) | VAF 50/146 reads (34%) | catalogued as rs763747066, COSV64687563; called by muse, mutect2, varscan2
- PLXND1 | c.5466C>A p.L1822= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV60713285; called by muse, mutect2, varscan2
- PTK2 | c.2259C>A p.I753= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV61785770; called by muse, mutect2, varscan2
- RIC1 | c.2475G>A p.Q825= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs149258225; called by muse, mutect2, varscan2
- SAMD9 | c.750C>T p.I250= | Silent (SNP) | VAF 15/152 reads (10%) | catalogued as COSV66075169; called by muse, mutect2, varscan2
- SH3BP4 | c.702G>A p.R234= | Silent (SNP) | VAF 29/240 reads (12%) | catalogued as COSV60643933; called by muse, mutect2, varscan2
- VCPIP1 | c.3477A>G p.E1159= | Silent (SNP) | VAF 41/173 reads (24%) | catalogued as COSV60047290; called by muse, mutect2, varscan2
- WDR91 | c.750T>C p.N250= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV60369771; called by muse, mutect2, varscan2
- ZNF793 | c.360G>A p.G120= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV71324979; called by muse, mutect2
- BNIP1 | c.178-2732A>T | Intron (SNP) | VAF 20/118 reads (17%) | catalogued as rs955656456; called by muse, mutect2, varscan2
- MIR506 | n.18del | RNA (DEL) | VAF 32/161 reads (20%) | called by mutect2, varscan2
